Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANV, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AANV-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type:

*Date - Date of Service:

Document Status:

Document Title:

Author:

Authenticated By:

Encounter info:

Contributor system:

* Final Report *

MICROSCOPIC EXAMINATION:

A: See final microscopic-diagnosis.

INTRAOPERATIVE GROSS CONSULTATION

Seminoma

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Left testicle:

- Seminoma

ICD O-3

Seminoma NDS 906113

Site D Jastis NDS 062.9

AS 3/21/14

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Left testicle". It consists of a 72-gram orchiectomy specimen including testis (6 x 5 x 2 cm), epididymis (1.2 x 1 x 0.4 cm), and spermatic cord (9 cm length x 1.5 cm in diameter). There is a 5 x 4 x 2 cm tan-white, firm, circumscribed mass and homogeneous without any hemorrhage or necrosis noted on the surface within the testis. The tumor does not grossly extends into the tunica albuginea or into the epididymis. The remainder of the testicular parenchyma is tan-white with grossly normal tubules present. The spermatic cord consists of vas deferens, arteries and is grossly unremarkable. A piece of tumor measuring 1 x 0.8 x 0.2 cm is submitted for frozen section in cassette AFS. Representative sections are submitted in a total of nine cassettes, including frozen section.

SECTIONS:

AFS: frozen section, left testicle

A1: margin of the spermatic cord

Printed by:

Printed on:

Page 1 of 2

(Continued)

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

* Final Report *

A2,3: tumor with albuginea
A4-8: tumor

Signature Line

CLINICAL INFORMATION:

Pre-Op Dx: Left testicular mass
Post-Op Dx: Same as preop
operation: Left radical orchiectomy

SPECIMEN SOURCE:

A: "Left testicle"

DIAGNOSIS:

LEFT RADICAL ORCHIECTOMY:

LEFT TESTICLE (A):

- SEMINOMA, 5.0 X 4.0 X 2.0 CM
- NO DEFINITE EVIDENCE OF ANGIOLYMPHATIC INVASION
- THERE IS NO EVIDENCE OF INTRATUBULAR GERM CELL NEOPLASM (IGCN)
- THE TUMOR DOES NOT EXTEND TO OR THROUGH TUNICA ALBUGINEA OR TUNICA VAGINALIS
- THE TUMOR DOES NOT EXTEND INTO THE EPIDIDYMIS BUT IS FOCALLY VERY CLOSE TO THE RETE TESTES
- NO LYMPH NODES WERE SUBMITTED FOR EVALUATION

PATHOLOGIC STAGING: T2CNXX

Signature Line

Electronically signed by
Verified:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 8c7578ef-57b5-47be-a177-5a16a069a499 (TCGA-XE-AANV.C2F7D5BE-538F-4414-ABA2-84EE0C916BBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).